Somatic mutation profile of tumor specimen TARGET-50-PAJMEP-01A (aliquot TARGET-50-PAJMEP-01A-01D) from TARGET case TARGET-50-PAJMEP, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: male; Vital status: Dead; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 1.8 years (670 days).
Specimen TARGET-50-PAJMEP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c4dd791-1186-47aa-bf3f-347f2c626a43.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAJMEP-11A (Solid Tissue Normal), aliquot TARGET-50-PAJMEP-11A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6920a3b3-2f41-44cc-b920-f6d7cc317039

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CUEDC1 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1354471442, COSV64226948; called by muse, mutect2
- FAM71E2 | c.1946C>A p.A649E | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.98); PolyPhen benign (0.055); catalogued as rs879212596; called by muse, mutect2, varscan2
- NAV2 | c.5480_5482del p.K1827del (on ENST00000396087 / NM_001244963.2; = p.K1771del on NM_145117.5) | In Frame Del (DEL) | VAF 5/45 reads (11%) | catalogued as rs777669469; called by mutect2, pindel
